Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NV, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NV-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

70-year-old male with long history of reflux. Recent onset dysphagia/weight loss. Evaluation indicates adenocarcinoma. No chemo or x-ray therapy.

PROCEDURE:

VERIFIED BY:

1. "Esophagus." A 13.0 x 7.0 x 2.5 cm specimen comprised of 7 cm of distal esophagus and 6 cm of proximal stomach. Received opened longitudinally. At the GE junction there is a somewhat nodular thickening of the mucosa, 1.5 x 1.5 cm. Maximum depth of lesion 1.3 cm. Remainder of the GE junction shows slight irregularity and possible ulceration. Distal and proximal staple lines removed. Deep inked black.
- 1A-B. Distal stomach resection margin.
- 1C. Proximal uninvolved esophagus, proximal end inked black.
- 1D-G. Sections through major portion of lesion.
- 1H-J. Lymph node dissection.
2. "Cervical esophageal margin." A 3.2 x 2.0 x 2.0 cm length of esophagus closed at one end with staple line.
- 2A. Stapled end.
- 2B. Non-stapled end.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: ~~esoph~~ Esophagus, distal third C15.5
Gastroesophageal junction C16.0
8/5/17/14

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma

If adenocarcinoma, is it arising in: GE junction

Depth of invasion: Omental surface

Number of positive lymph nodes, the total number sampled is irrelevant: 0

Extranodal metastasis: Unknown

Pattern of invasion: Infiltrative

Esophageal and gastric resection margins involved: No

Deep resection margin involved: Yes

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

TNM classification: T2N0Mx

PROCEDURE:

VERIFIED BY:

1. Esophagus, resection: Moderately to poorly differentiated adenocarcinoma arising from the gastroesophageal junction (1.5 cm). Tumor penetrates muscularis propria and reaches the omentum surface. Distal gastric margin negative for neoplasm. Four lymph nodes negative for neoplasm. See template.

2. Cervical esophageal margin, resection: Negative for neoplasm.

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Rele	W 11/19/13	Yes	No
Metastatic/Synchronous Primary Noted			

Source: NCI Genomic Data Commons file 0baaa93e-2b1b-4ea0-b840-6ba94a4de652 (TCGA-L5-A8NV.430218E3-EEB1-47CA-B907-4AA14D8A13EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).